Surgical pathology report (de-identified scan), TCGA case TCGA-19-2623, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-2623-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT**FINAL DIAGNOSIS**

A. RIGHT FRONTAL LOBE OF BRAIN, TUMOR, BIOPSY AND REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

Touch Imprint and Microscopic: High grade glioma.

Clinical History:

r frontal tumor

Specimens Submitted As:

A:RIGHT FRONTAL TUMIOR
B:FRONTAL LOBE TUMOR

Gross Description:

A: Received fresh, for intraoperative consultation, labelled with the patient's name and number, is an irregular segment of red-tan, soft tissue, 2.0 x 1.2 x 0.2 cm. A portion of the specimen is submitted for frozen analysis, and the remainder of the specimen is submitted for permanent sections.

B: Received in formalin, labeled with the patient's name and number, are six light tan to brown irregular to wedge-shaped soft tissue fragments ranging from 0.5 x 0.4 x 0.2 cm 1.8 x 1.7 x 0.6 cm. The largest fragments are serially sectioned. On section, the tissue is light tan and lobulated. Submitted entirely in four cassettes.

Summary of cassettes

A1 frozen section

A2 frozen section

A3 remainder of red-tan, soft tissue

B1-B2 sectioned fragments

B3-B4 remaining tissue

Source: NCI Genomic Data Commons file ad3dd178-053d-4f97-a13c-5cfaec87b32f (TCGA-19-2623.7B05B633-98C5-4474-86D3-8E8748A27B80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).